Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3AD, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3AD-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, cervical C29.0
w/ 9/21/11

CLINICAL DETAILS

Tumour over (R) mastoid process FNB suggests metastatic melanoma (No known primary). Tumour (R) mastoid region. ?lymph node ?tumour adjacent to mass.

MACROSCOPIC DESCRIPTION

Two specimens received.

1. "TUMOUR RIGHT MASTOID". An ellipse of skin 40 x 12 to a depth of 23mm with subcutis up to 24mm wide. The cut surface shows a cream tumour nodule in the subcutis measuring 18 x 12 x 12mm which abuts the deep excision margin. Two representative sections with closest margins embedded in Blocks A & B. S100 and HMB-45 and Melan A ordered.
2. "?LYMPH NODE ?TUMOUR RIGHT MASTOID". A fragment of pale fibrous tissue 14 x 7 x 4mm. Processed whole.

MICROSCOPIC REPORT

1. "TUMOUR RIGHT MASTOID".
The sections show a nodule of malignant spindle and epithelioid tumour almost replacing a lymph node. No pigment is present but there is strong positive staining for S100, HMB-45 and Melan-A, consistent with metastatic melanoma. There is no extranodal extension. The margins appear clear by about 0.4mm from the nearest, deep, plane of excision.
2. "?LYMPH NODE ?TUMOUR RIGHT MASTOID".
The specimen consists of adipose tissue and skeletal muscle. There is no evidence of malignancy. No lymph node is present.

SUMMARY

RIGHT CERVICAL LYMPH NODE, MASTOID REGION - METASTATIC MELANOMA

REPORTED BY: .

Printed:

Page 1 of 1

This fax was received at

For more information, visit:

Source: NCI Genomic Data Commons file c6e862cd-2d63-48ef-ac1a-e34b7ab0172d (TCGA-EE-A3AD.B9063550-43F3-47DC-82D8-46C426998629.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).